Somatic mutation profile of tumor specimen 0DW6BO from CCDI case PBCNHZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.9 years (1,438 days).
Specimen 0DW6BO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81936eb9-a533-4fa6-ac30-d269941019ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW6AZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a5855a8-e5b7-4a99-b615-d12e8f962275

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'Flank 2, Silent 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSNK1D | c.620A>G p.N207S | Missense Mutation (SNP) | VAF 81/640 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); catalogued as rs199554561; called by muse, mutect2, varscan2
- IGSF8 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 139/315 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs766702449, COSV58757487; called by muse, mutect2, varscan2
- BANK1 | c.2053G>T p.E685* | Nonsense Mutation (SNP) | VAF 252/615 reads (41%) | called by muse, mutect2, varscan2
- MTERF1 | c.1038C>G p.I346M | Missense Mutation (SNP) | VAF 304/794 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- NUP160 | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 153/368 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- CDH4 | c.1737C>T p.N579= | Silent (SNP) | VAF 32/1084 reads (3%) | catalogued as rs991980847; called by muse, mutect2
- GAGE2E | c.297G>A p.P99= | Silent (SNP) | VAF 22/288 reads (8%) | called by muse, mutect2
- AC023141.7 | n.31C>A | RNA (SNP) | VAF 11/61 reads (18%) | called by mutect2, varscan2
- SKIV2L | chr6:31959124 del GGCGGGGCTTACTTCGCAGCGACTACTTGCCGCACTTCCGGGCTGCCA | 5'Flank (DEL) | VAF 207/695 reads (30%) | called by mutect2, pindel, varscan2
- WASHC3 | chr12:102062057 G>T | 5'Flank (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
